Gene-level copy-number profile of tumor specimen TCGA-CM-6170-01A from TCGA case TCGA-CM-6170, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Descending colon; AJCC pathologic stage: Stage I; Age at diagnosis: 73.0 years (26,663 days).
Specimen TCGA-CM-6170-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.776b6b01-24ef-4b2d-af91-f979277eff39.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CM-6170-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a0c74915-952f-4b32-a362-4afc1acd8519

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 26; copy number 1: 14,580; copy number 2: 40,588; copy number 3: 3,369; copy number 4: 250; copy number 5: 1,005.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CM-6170-01A-11D-1649-01): tumor purity 0.78, ploidy 1.87, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 26 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:39,623,435–39,691,485, 4 genes (within-gene range 0–2): HEYL, AL035404.2, NT5C1A, HPCAL4.
- chr4:91,319,034–91,605,292, 2 genes (within-gene range 0–1): AC074124.1, AC110774.1.
- chr4:150,720,981–150,721,478, 1 gene: ZBTB8OSP1.
- chr12:114,894,632–114,898,529, 1 gene: AC009804.2.
- chr21:32,772,100–33,310,187, 18 genes (within-gene range 0–1): C21orf62-AS1, AP000280.2, C21orf62, AP000281.1, SNORA70, AP000281.2, AP000282.1, LINC01690, OLIG2, LINC00945, OLIG1, AP000289.1, AP000290.1, LINC01548, IFNAR2, AP000295.1, IL10RB-DT, IL10RB.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,005 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:23,439,685–64,313,132, 1,005 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 14,580. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
